TCGA case TCGA-CM-6170 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9d8c4693-8e36-473b-bb34-a7cdc04dd223

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.6; Tissue or organ of origin: Descending colon; Site of resection or biopsy: Descending colon; Classification of tumor: primary; Age at diagnosis: 73.0 years (26,663 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 457 days (1.3 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 12; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 242 days; Disease response: Tumor Free.
- Days to follow up: 457 days (1.3 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 0.8 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85.8 kg; Height: 145 cm; BMI: 40.8.
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CM-6170-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.9; Shortest dimension: 0.4.
  Slide TCGA-CM-6170-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 70; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 15.
  Slide TCGA-CM-6170-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 65; Percent normal cells: 25; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-CM-6170-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CM-6170-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 0.8; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Colon polyps at procurement indicator: Yes; Mismatch rep proteins tested by IHC: No.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 457 days; disease-specific survival: no event (censored), 457 days; progression-free interval: no event (censored), 457 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CM-6170-01A-11D-1649-01): tumor purity 0.78, ploidy 1.87, whole-genome doublings 0.
